Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1BL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1BL-01A (Primary Tumor).

ICD-0-3
Carcinoma, squamous cell, NOS 8070/3
Site Code: Cervix, NOS C53.9 12/29/10 lw

**** Consult Case ****

Name: [REDACTED]
Address: [REDACTED]

Surg. Path. No.: [REDACTED]
DOB: [REDACTED]
Sex/Race: [REDACTED]
Service: INSIDE/OUTSIDE
Date Received: [REDACTED]

DIAGNOSIS

UTERUS, CERVIX, BIOPSY - MODERATELY DIFFERENTIATED SQUAMOUS CELL
CARCINOMA, SEE COMMENT

HISTORY

(None Given)

GROSS

Submitted for review by Dr. [REDACTED] is one (1) slide labelled
accompanied by a corresponding pathology report. The
material originates from [REDACTED]

COMMENT

The histologic examination of the cervical biopsy shows different
sized nodules composed of markedly enlarged squamous cells with a
prominent nucleus. The nuclei is pleomorphic. Single-cell
dyskeratosis on increased numbers of atypical mitoses are present.
These findings correspond to a moderately differentiated squamous
cell carcinoma. The stroma of the tumor shows moderate

Reviewer Initials: [REDACTED] Date Reviewed: 12/29/10		

Source: NCI Genomic Data Commons file 58d53fbf-4c81-4cac-bf9a-95534880eb86 (TCGA-C5-A1BL.C3312E18-832F-4126-8E9E-F829128F7530.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).